Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5467, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5467-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Report Status: Amend/Addenda

Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Lymph node biopsy (non-heme)
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

TCGA-CZ-5467

PATIENT

***** Added Report ****

PATHOLOGIC DIAGNOSIS:

A. SPECIMEN LABELED "RETROPERITONEAL NODE":
Two (2) lymph nodes negative for tumor.

B. SPECIMEN LABELED "RT KIDNEY":
RENAL CELL CARCINOMA, clear cell type (11.0 cm), Fuhrman grade IV, with focal sarcomatoid differentiation, involving the middle and upper pole.
Tumor invades small (non-muscular) vein.
Tumor invades perinephric adipose tissue.
Soft tissue resection margins are negative for tumor. Tumor is <0.1 cm of the margin.

Renal artery, vein and ureter margins are negative for tumor.
Portion of adrenal gland negative for tumor.

AJCC/3a/O/X.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

Part B of this case was reviewed by Dr. [REDACTED] Pathology Division, who concurs with the diagnosis.

CLINICAL DATA:

History: R renal mass invading psoas + liver.
Operation: Nephrectomy.
Operative Findings: Not provided.
Clinical Diagnosis: None given.

TISSUE SUBMITTED:

- A. Retroperitoneal node.
- B. Rt kidney.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, "#1. Retroperitoneal node", consists of one pink/red fragment of soft tissue (2.3 x 1.1 x 0.3 cm). No lymph nodes are identified. The entire specimen is submitted for histologic examination.

Micro A1: 1 frag, [REDACTED]

Part B, "#2. RT kidney", consists of a radical nephrectomy specimen (762.5 gram, 21.0 x 10.0 x 8.8 cm) with ureter (4.5 cm in length x 0.2 cm in diameter), possible arteries (5.0 cm in length x 0.5 cm in diameter), vein #1 (2.2 cm in length x 0.7 cm in diameter), vein #2 (2.2 cm in length x 0.2 cm in diameter), and a portion of disrupted adrenal gland (5.0 x 1.5 x 0.8 cm) without masses or lesions grossly. A tan/red to tan/yellow, encapsulated mass (11.0 x 9.5 x 8.2 cm) is located in the upper pole 10.0 cm from the ureter margin, 5.5 cm from the vein #1 margin, 2.0 cm from vein #2 margin, 4.3 cm from the artery margin, and abutting the outer surface of the specimen (inked black). Approximately 70% of the tumor is hemorrhagic with approximately 50% necrosis in multiple nodules. The remainder of the mass is tan/white and homogenous, and present as a single nodule in the lower part of the mass abutting the more hemorrhagic nodule. The uninvolved renal parenchyma is

[page 2 of 4]
Pathology Report

pink/tan and unremarkable. Gross photographs are taken. Representative sections of the tumor are submitted for cytogenetics, tissue bank and Dr. [REDACTED] lab. Representative sections of uninvolved kidney are submitted for EM, IF and tissue bank. No lymph nodes are identified.

Micro B1: Ureter, artery, and vein margins, 4 frags, [REDACTED]
Micro B2: Tumor quick fix (T1), hemorrhagic/necrotic area, 1 frag, [REDACTED]
Micro B3: Tumor quick fix (T2), tan/white/homogenous areas, 1 frag, [REDACTED]
Micro B4: Tumor T1 with respect to T2, 1 frag, [REDACTED]
Micro B5-B6: Tumor with respect to Gerota's fascia, 1-2 frags each, [REDACTED]
Micro B7: Tumor with respect to perirenal adipose tissue, ? invasion, 1 frag, [REDACTED]
Micro B8: Tumor with respect to renal parenchyma, 1 frag, [REDACTED]
Micro B9: Adrenal gland, 4 frags, [REDACTED]
Micro B10: Uninvolved renal parenchyma, 1 frag, [REDACTED]

CASE NUMBER: [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by [REDACTED]

Electronically signed on [REDACTED]

ADDENDUM #1:

B. SPECIMEN LABELED "RT KIDNEY":
Staging should read as follows:
AJCC Classification (6th edition): T3a N0 MX.

The diagnosis remains unchanged.

Addendum #1 by [REDACTED]

ADDENDUM:

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

RIGHT KIDNEY, NEPHRECTOMY:

MILD CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, MOST LIKELY AGE-RELATED, INCLUDING:

- FOCAL GLOBAL GLOMERULOSCLEROSIS, (1.1% OF GLOMERULI);
- FOCAL TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (<5% OF THE PARENCHYMA)
- ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATE (SEE NOTE)

NOTE:

The kidney parenchyma examined shows minimal chronic changes, as summarized above.

The kidney parenchyma has been evaluated by [REDACTED] Renal Pathologist.

[page 3 of 4]
[REDACTED]

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block B10) were evaluated using H&E, PAS, Jones' silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 373 glomeruli present, of which 4 (1.1%) are globally sclerosed. The remaining glomeruli show no significant expansion of the mesangial areas. There are no discernible craters or double contours of the glomerular capillary wall basement membranes. Rare distal tubules contain PAS-positive hyaline casts. Less than 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit moderate sclerosis and hyalinosis.

[REDACTED]

[page 4 of 4]
Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist: [REDACTED]

Report Status: Final

KARYOTYPE: T1:
47,X,-X,der(3)t(3;14)(p2?1;q2?2),del(14)(q2?2),+16,+18[cp5]/46,XX[2]

METAPHASES COUNTED: 7 ANALYZED: 7 SCORED: 0 BANDING: GTG

INTERPRETATION:

Five of 7 metaphases obtained from sample T1, contained the clonal aberrations described above, including loss of the short arm of chromosome 3, der(3), a characteristic finding in renal cell carcinoma, clear cell type.

Cell cultures from specimen T2 were attempted but unsuccessful, and the cytogenetic analysis could not be performed.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC

[REDACTED]

Source: NCI Genomic Data Commons file cb264ca6-4d91-440f-b3ef-f37fa2a54d43 (TCGA-CZ-5467.9C47B43A-CB8D-4F92-99DE-40435A57C5E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).